Somatic mutation profile of tumor specimen TCGA-AA-3818-01A (aliquot TCGA-AA-3818-01A-01W-0900-09) from TCGA case TCGA-AA-3818, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.7 years (28,763 days).
Specimen TCGA-AA-3818-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed8f06e0-4957-4664-ad80-03f2e804b38d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3818-10A (Blood Derived Normal), aliquot TCGA-AA-3818-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2975ae22-dec1-4fe6-824f-816153f02688

The open-access MAF lists 156 somatic variants for this specimen: 114 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 39, Nonsense Mutation 10, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 1, RNA 1, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs72653136, CM090258, CM880015, COSV56802216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 44/133 reads (33%) | catalogued as COSV64670775; called by muse, mutect2, varscan2
- ABCG1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs756708334, COSV59200214; called by muse, mutect2, varscan2
- AC092143.1 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59246959; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299715981, COSV58441120; called by muse, mutect2, varscan2
- AKAP4 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62073548; called by muse, mutect2
- ALK | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV66556029; called by muse, mutect2, varscan2
- ANK1 | c.3209G>T p.C1070F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV55871756; called by muse, mutect2, varscan2
- APC | c.4233del p.S1411Rfs*4 | Frame Shift Del (DEL) | VAF 68/195 reads (35%) | catalogued as COSV57321189; called by mutect2, pindel, varscan2
- ASH1L | c.3478C>T p.R1160W | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs145739954; called by muse, mutect2, varscan2
- ATXN3L | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 83/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66075188; called by muse, mutect2, varscan2
- BATF3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1421187861, COSV54657559; called by muse, mutect2, varscan2
- BOC | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as COSV56346747; called by muse, mutect2, varscan2
- BRINP1 | c.1595A>G p.K532R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs373828125, COSV56291180; called by muse, mutect2, varscan2
- BRINP3 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV66512054; called by muse, mutect2, varscan2
- CARF | c.1035G>C p.M345I | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV57546105; called by muse, mutect2, varscan2
- CARMIL1 | c.2191A>G p.K731E | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61513267; called by muse, mutect2, varscan2
- COPB1 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755402317, COSV51446582; called by muse, mutect2, varscan2
- CPVL | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV55298761; called by muse, mutect2, varscan2
- CREBBP | c.5424C>A p.C1808* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52113108; called by muse, mutect2, varscan2
- CSMD1 | c.4492A>T p.N1498Y (on ENST00000520002; = p.N1497Y on NM_033225.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59277950; called by muse, mutect2
- CTNND1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100650249, COSV62386487; called by muse, mutect2
- DESI1 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV54353956; called by muse, mutect2, varscan2
- DGKD | c.1069G>A p.G357R (on ENST00000264057 / NM_152879.3; = p.G313R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99897384; called by muse, mutect2
- DIAPH3 | c.3397G>A p.A1133T | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs188721921, COSV100931128; called by muse, mutect2
- DNAH5 | c.6640C>A p.L2214M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV54202079; called by muse, mutect2
- DNMT3B | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.947); catalogued as rs149520896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTWD1 | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 63/167 reads (38%) | catalogued as COSV52070940; called by muse, mutect2, varscan2
- DYRK4 | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV50537668; called by muse, mutect2, varscan2
- EGF | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.208); catalogued as COSV54475926, COSV99491301; called by muse, mutect2
- EIF2AK3 | c.1764-1G>C p.X588_splice | Splice Site (SNP) | VAF 6/115 reads (5%) | catalogued as COSV100304048; called by muse, mutect2
- EPG5 | c.2863C>T p.R955* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as rs761554022, COSV56344253; called by muse, mutect2, varscan2
- ERBB4 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV61459577; called by muse, mutect2, varscan2
- FAM47B | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 288/692 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs151033833, COSV61452310; called by muse, mutect2, varscan2
- FNDC11 | c.839A>T p.K280M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs372558520; called by muse, mutect2, varscan2
- FREM2 | c.4109T>G p.F1370C | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54827232; called by muse, mutect2
- GATA6 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52524369; called by muse, mutect2, varscan2
- GJA8 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV53787644; called by muse, mutect2
- GKN1 | c.88A>G p.N30D | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV65006173; called by muse, mutect2, varscan2
- GRID2 | c.1037A>T p.K346M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56169261; called by muse, mutect2, varscan2
- HDC | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as COSV99984274; called by muse, mutect2
- HRNR | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs754771130, COSV100913304, COSV64253745; called by muse, mutect2, varscan2
- HUWE1 | c.9521G>A p.R3174H | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53333498; called by muse, mutect2, varscan2
- ICE1 | c.6145G>T p.A2049S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56818509; called by muse, mutect2
- IFNAR2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as rs768028214, COSV51613835; called by muse, mutect2, varscan2
- IGF1R | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51269461; called by muse, mutect2, varscan2
- ITGA4 | c.2018C>T p.T673M | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs199911081, COSV67896144; called by muse, mutect2, varscan2
- KDM5B | c.2219A>T p.D740V | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV52503644; called by muse, mutect2, varscan2
- KNTC1 | c.5842A>G p.K1948E | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61078675; called by muse, mutect2, varscan2
- KYNU | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs141632644; called by muse, mutect2, varscan2
- LNX2 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60334122; called by muse, mutect2, varscan2
- LPA | c.3076G>A p.V1026I | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs759100515, COSV60295959, COSV60307886, COSV60309914; called by muse, mutect2, varscan2
- LTK | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV53026422; called by muse, mutect2, varscan2
- MAGEC2 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 231/1089 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.145); catalogued as rs769500609, COSV55997565; called by muse, mutect2, varscan2
- MAP2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 45/115 reads (39%) | catalogued as COSV52280023; called by muse, mutect2, varscan2
- MAP3K15 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs757126412, COSV58827054; called by muse, mutect2, varscan2
- MFAP5 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 106/385 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100848109, COSV63945004; called by muse, mutect2, varscan2
- MMP9 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63433718; called by muse, mutect2, varscan2
- MRAP2 | c.39G>T p.Q13H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57631348; called by muse, mutect2, varscan2
- MXRA5 | c.7691G>T p.C2564F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54222660; called by muse, mutect2, varscan2
- MYH1 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 237/292 reads (81%) | catalogued as rs768724975, COSV55430953; called by muse, mutect2, varscan2
- MYNN | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 6/172 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100582283; called by muse, mutect2
- MYO5A | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 130/307 reads (42%) | catalogued as rs1330819225, COSV62556283; called by muse, mutect2, varscan2
- NAP1L3 | c.747A>T p.K249N | Missense Mutation (SNP) | VAF 29/548 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV100220609, COSV59075001; called by muse, mutect2
- NELL2 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 87/154 reads (56%) | catalogued as rs1029371436, COSV61568219; called by muse, mutect2, varscan2
- NRXN2 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs539415834, COSV55455102; called by muse, mutect2, varscan2
- ONECUT1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59947615; called by muse, mutect2, varscan2
- OR5K3 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 32/868 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV101051675; called by muse, mutect2
- OR8J1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs150618551, COSV57316407; called by muse, mutect2, varscan2
- OSMR | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57080547; called by muse, mutect2, varscan2
- PCDH7 | c.2554C>A p.Q852K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV62336137; called by muse, mutect2, varscan2
- PCDH9 | c.2592G>T p.K864N | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60525228; called by muse, mutect2, varscan2
- PCDHAC1 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99169369; called by muse, mutect2
- PCDHB5 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.035); catalogued as COSV50647151; called by muse, mutect2, varscan2
- PER3 | c.2395G>T p.V799F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV62704202, COSV62704422; called by muse, mutect2, varscan2
- PPP1R26 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1357754211, COSV63354577; called by muse, mutect2, varscan2
- PRRC2C | c.6173T>G p.F2058C (on ENST00000367742; = p.F2056C on NM_015172.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58900459; called by muse, mutect2, varscan2
- PTGFRN | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 225/561 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs371176280; called by muse, mutect2, varscan2
- PTOV1 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377067186, COSV99681829; called by muse, mutect2, varscan2
- PTPRM | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1249149468, COSV100158312, COSV59842548, COSV59877926; called by muse, mutect2, varscan2
- PYHIN1 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.094); catalogued as COSV63729560; called by muse, mutect2, varscan2
- RELN | c.6874C>T p.R2292C | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs762032224, COSV58984203; called by muse, mutect2, varscan2
- RFX7 | c.2639G>A p.R880Q (on ENST00000559447 / NM_001368074.1; = p.R977Q on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs756963590, COSV57959318; called by muse, mutect2, varscan2
- RNF40 | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61213351; called by muse, mutect2, varscan2
- RP1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs367600337, COSV55109473, COSV55128616; called by muse, mutect2, varscan2
- RTL3 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58183628; called by muse, mutect2
- RUNX1 | c.703C>T p.Q235* (on ENST00000344691 / NM_001001890.3; = p.Q262* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as CM1210373, COSV100277318, COSV55866493; called by muse, mutect2, varscan2
- RYR1 | c.14686G>A p.G4896R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568611478, COSV62087771; ClinVar: uncertain significance; called by muse, mutect2
- SCARB2 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV99358094; called by muse, mutect2
- SCML2 | c.1412G>T p.R471M | Missense Mutation (SNP) | VAF 386/939 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV52618105; called by muse, mutect2, varscan2
- SENP7 | c.2060C>A p.A687D | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.273); catalogued as COSV58607328; called by muse, mutect2, varscan2
- SLC10A2 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV55356893; called by muse, mutect2, varscan2
- SLC18A2 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53688296, COSV53692299; called by muse, mutect2, varscan2
- SLC25A3 | c.566G>A p.R189Q (on ENST00000228318 / NM_005888.3; = p.R188Q on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV51844186; called by muse, mutect2
- SLC2A14 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100533976; called by muse, mutect2
- SLCO2B1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs745594123, COSV56932748; called by muse, mutect2, varscan2
- SNX25 | c.2078T>C p.F693S | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV53011183; called by muse, mutect2, varscan2
- STYXL1 | c.191A>T p.E64V | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV99951617; called by muse, mutect2, varscan2
- TADA3 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV55027858; called by muse, mutect2, varscan2
- TENM1 | c.221T>A p.M74K | Missense Mutation (SNP) | VAF 81/541 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV64424305; called by muse, mutect2, varscan2
- TSHZ3 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1450365947, COSV53663468; called by muse, mutect2, varscan2
- TTN | c.74444A>G p.E24815G (on ENST00000591111; = p.E17391G on NM_003319.4) | Missense Mutation (SNP) | VAF 18/152 reads (12%) | PolyPhen possibly damaging (0.793); catalogued as COSV59869299; called by muse, mutect2, varscan2
- UGT2B28 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 113/288 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59430390; called by muse, mutect2
- UPF2 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs180827437, COSV62657955; called by muse, mutect2, varscan2
- WDPCP | c.1013C>A p.S338* | Nonsense Mutation (SNP) | VAF 210/515 reads (41%) | catalogued as COSV55412235; called by muse, mutect2, varscan2
- YLPM1 | c.5833T>C p.W1945R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53105480; called by muse, mutect2, varscan2
- ZDBF2 | c.6314C>T p.A2105V | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs780769661, COSV65621421; called by muse, mutect2, varscan2
- ZNF606 | c.1494T>A p.H498Q | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.641); catalogued as COSV100071984; called by muse, mutect2
- ZZEF1 | c.2715-1G>T p.X905_splice | Splice Site (SNP) | VAF 142/167 reads (85%) | catalogued as COSV101067992; called by muse, mutect2, varscan2
- APC | c.2881_2882dup p.N961Kfs*5 | Frame Shift Ins (INS) | VAF 55/153 reads (36%) | called by mutect2, pindel, varscan2
- FBXW7 | c.787dup p.T263Nfs*24 (on ENST00000281708 / NM_001349798.2; = p.T183Nfs*24 on NM_018315.5) | Frame Shift Ins (INS) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- KANSL1L | c.1961dup p.T655Dfs*2 | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF1 | c.2370C>T p.N790= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs376174015; called by muse, mutect2
- ARL13A | c.237G>T p.R79= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV100879031; called by muse, mutect2
- AVIL | c.2361A>G p.E787= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV57680205; called by muse, mutect2, varscan2
- BTN3A1 | c.1326G>A p.R442= | Silent (SNP) | VAF 49/374 reads (13%) | catalogued as COSV50024416; called by muse, mutect2, varscan2
- CALCRL | c.702C>G p.G234= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV66473292; called by muse, mutect2, varscan2
- CCR8 | c.633C>T p.F211= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV58336675; called by muse, mutect2, varscan2
- CNTNAP5 | c.2865C>A p.G955= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV70470465; called by muse, mutect2, varscan2
- COL11A1 | c.2730C>T p.G910= | Silent (SNP) | VAF 7/184 reads (4%) | catalogued as COSV100617881; called by muse, mutect2
- CYSLTR1 | c.135C>G p.L45= | Silent (SNP) | VAF 61/282 reads (22%) | catalogued as COSV64819292; called by muse, mutect2, varscan2
- DMBT1 | c.7488G>A p.A2496= (on ENST00000338354 / NM_001377530.1; = p.A1739= on NM_004406.3) | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs755724436, COSV57533206; called by muse, mutect2, varscan2
- DUSP7 | c.1158G>A p.G386= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1467421389, COSV56588560; called by muse, mutect2, varscan2
- GGA1 | c.1254C>T p.S418= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1191882303, COSV57328724; called by muse, mutect2, varscan2
- IGHV5-51 | c.81A>C p.G27= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.192C>A p.P64= | Silent (SNP) | VAF 72/238 reads (30%) | called by muse, mutect2
- KCNQ4 | c.1974G>A p.P658= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV61271898; called by muse, mutect2, varscan2
- KIR2DL4 | c.1188G>A p.R396= (on ENST00000396284; = p.R322= on NM_001080770.2) | Silent (SNP) | VAF 136/498 reads (27%) | called by muse, mutect2, varscan2
- KLHDC8B | c.918G>A p.R306= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV60411231; called by muse, mutect2, varscan2
- MAGEB18 | c.510C>A p.I170= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV57463301; called by muse, mutect2, varscan2
- MAGEC1 | c.672T>G p.T224= | Silent (SNP) | VAF 397/2982 reads (13%) | catalogued as COSV99596368; called by muse, varscan2
- MAGEH1 | c.651C>T p.S217= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV100746836; called by muse, mutect2
- MAK16 | c.594C>T p.D198= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100659797; called by muse, mutect2
- MUC6 | c.6630C>T p.A2210= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV70132414; called by muse, mutect2
- NEB | c.9261C>T p.S3087= | Silent (SNP) | VAF 148/336 reads (44%) | catalogued as COSV50806432; called by muse, mutect2, varscan2
- PCDHGA1 | c.2190C>T p.G730= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as COSV65294725; called by muse, mutect2, varscan2
- PCDHGA8 | c.1620G>A p.P540= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs1180818373, COSV53893877; called by muse, mutect2, varscan2
- PDE1C | c.1527T>A p.T509= | Silent (SNP) | VAF 115/253 reads (45%) | catalogued as COSV100373605; called by muse, mutect2, varscan2
- PRC1 | c.1467C>T p.N489= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as rs773584087, COSV62694044; called by muse, mutect2, varscan2
- PRLHR | c.918C>T p.H306= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53302718; called by muse, mutect2, varscan2
- SELENBP1 | c.1134C>A p.V378= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV64372889; called by muse, mutect2
- SERPINC1 | c.1077C>T p.D359= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs773134244, COSV62928797; called by muse, mutect2, varscan2
- SLFNL1 | c.1044C>T p.R348= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs140281244; called by muse, mutect2, varscan2
- SLITRK4 | c.2061T>A p.I687= | Silent (SNP) | VAF 134/301 reads (45%) | catalogued as COSV62021891; called by muse, mutect2, varscan2
- SVIL | c.2238C>T p.I746= (on ENST00000355867 / NM_021738.3; = p.I352= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs757805709, COSV63439365; called by muse, mutect2, varscan2
- TDP1 | c.147C>T p.S49= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs761583949, COSV59641957; called by muse, mutect2, varscan2
- TERF2 | c.1530A>G p.G510= | Silent (SNP) | VAF 75/235 reads (32%) | catalogued as COSV54746347; called by muse, mutect2, varscan2
- TRIB3 | c.504C>T p.T168= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs966310234, COSV53930275; called by muse, mutect2, varscan2
- USH2A | c.12621C>T p.A4207= | Silent (SNP) | VAF 160/394 reads (41%) | catalogued as rs369544099, COSV56325711; called by muse, mutect2, varscan2
- WFDC1 | c.354G>A p.V118= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV54742850; called by muse, mutect2
- ZNF233 | c.1767G>A p.E589= | Silent (SNP) | VAF 68/417 reads (16%) | catalogued as COSV61933168; called by muse, mutect2, varscan2
- FAM183BP | n.1128G>A | RNA (SNP) | VAF 16/252 reads (6%) | catalogued as rs745901723; called by muse, mutect2
- MAGEC3 | c.1124-211C>G | Intron (SNP) | VAF 72/492 reads (15%) | catalogued as COSV53575728; called by muse, mutect2, varscan2
- SAMD9L | c.*1G>T | 3'UTR (SNP) | VAF 52/609 reads (9%) | catalogued as COSV100561079; called by muse, mutect2
